Somatic mutation profile of tumor specimen TCGA-34-2600-01A (aliquot TCGA-34-2600-01A-01W-0877-08) from TCGA case TCGA-34-2600, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.9 years (28,072 days).
Specimen TCGA-34-2600-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c759d22-751b-457e-8894-e981d2008edd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2600-11A (Solid Tissue Normal), aliquot TCGA-34-2600-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27ab7736-036c-43b3-8a9f-34849b9e8d9d

The open-access MAF lists 442 somatic variants for this specimen: 331 protein-altering or splice-affecting, 99 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 276, Silent 99, Nonsense Mutation 25, Frame Shift Ins 14, Intron 9, Splice Site 8, Frame Shift Del 5, Splice Region 3, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 40/259 reads (15%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CRX | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs863224863, CM113154, COSV55759682; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.939+1169C>G | Intron (SNP) | VAF 15/134 reads (11%) | catalogued as rs1057519791, COSV100336065; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.453dup p.T152Hfs*180 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | catalogued as rs761863251; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PDGFRA | c.2524G>C p.D842H | Missense Mutation (SNP) | VAF 15/207 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57269122, COSV57271881; called by muse, mutect2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 39/44 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSL6 | c.2012C>A p.T671K (on ENST00000379240; = p.T696K on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57303276; called by muse, mutect2, varscan2
- ACTG2 | c.701C>A p.S234Y | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as rs747982211, COSV61829328; called by muse, mutect2, varscan2
- ADAM18 | c.1766C>G p.S589* | Nonsense Mutation (SNP) | VAF 51/104 reads (49%) | catalogued as COSV55846746, COSV55852491; called by muse, mutect2, varscan2
- ADAM21 | c.1299T>A p.C433* | Nonsense Mutation (SNP) | VAF 73/92 reads (79%) | catalogued as COSV50804005; called by muse, mutect2, varscan2
- ADCY8 | c.2595G>A p.M865I | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs267601770, COSV53921426; called by muse, mutect2, varscan2
- ADGRA3 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 111/120 reads (93%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.535); catalogued as rs746516223, COSV51562557; called by muse, mutect2, varscan2
- AK9 | c.2926C>T p.H976Y | Missense Mutation (SNP) | VAF 139/164 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV58147808; called by muse, mutect2, varscan2
- AKAP8 | c.504dup p.Q169Afs*4 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs752767200; called by pindel, varscan2
- AL031681.2 | c.3092G>C p.R1031T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV64229388; called by muse, mutect2
- ALDH1B1 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 213/284 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV66620449; called by muse, mutect2, varscan2
- ALMS1 | c.11705C>T p.T3902I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52518353; called by muse, mutect2, varscan2
- AMER3 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776499369, COSV58469046; called by muse, mutect2, varscan2
- ANXA1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 72/145 reads (50%) | catalogued as COSV57412286; called by muse, mutect2, varscan2
- ANXA5 | c.908A>T p.D303V | Missense Mutation (SNP) | VAF 60/66 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56639820; called by muse, mutect2, varscan2
- APOB | c.7819C>G p.L2607V | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV51947300; called by muse, mutect2, varscan2
- APOB | c.3323G>A p.G1108D | Missense Mutation (SNP) | VAF 84/132 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763870199, COSV51947314; called by muse, mutect2, varscan2
- ARHGEF9 | c.147G>T p.Q49H | Missense Mutation (SNP) | VAF 131/289 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as COSV53642540; called by muse, mutect2, varscan2
- ARID4B | c.2270C>T p.S757L | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV51608987; called by muse, mutect2
- ARMCX5 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 186/297 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV55767284; called by muse, mutect2, varscan2
- ASPM | c.6102G>T p.M2034I | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV54135882; called by muse, mutect2
- ASTN2 | c.3486C>A p.D1162E (on ENST00000313400 / NM_001365069.1; = p.D1111E on NM_014010.5) | Missense Mutation (SNP) | VAF 166/347 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56011913; called by muse, mutect2, varscan2
- ATP10A | c.3449T>A p.L1150Q | Missense Mutation (SNP) | VAF 70/105 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63521659; called by muse, mutect2, varscan2
- ATP10D | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.085); catalogued as COSV56711565; called by muse, mutect2
- ATP13A1 | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV52289971; called by muse, mutect2, varscan2
- ATP1B4 | c.670C>A p.R224S (on ENST00000218008 / NM_001142447.3; = p.R220S on NM_012069.5) | Missense Mutation (SNP) | VAF 121/194 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54314349, COSV54314984; called by muse, mutect2, varscan2
- AXDND1 | c.2767G>T p.A923S | Missense Mutation (SNP) | VAF 201/393 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV62646674; called by muse, mutect2, varscan2
- BAZ1A | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV62411738; called by muse, mutect2, varscan2
- BRCA1 | c.4030G>A p.D1344N | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as COSV58795803, COSV58796487; called by muse, mutect2
- BRCA1 | c.3343G>C p.E1115Q | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.957); catalogued as CD032452, COSV58796505; called by muse, mutect2
- BRD9 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51321422; called by muse, mutect2, varscan2
- C11orf58 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV57179068; called by muse, mutect2, varscan2
- C16orf46 | c.1042G>T p.V348L | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs575984281, COSV55152463; called by muse, mutect2, varscan2
- C2CD6 | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53798850; called by muse, mutect2, varscan2
- C2orf78 | c.1378T>G p.L460V | Missense Mutation (SNP) | VAF 101/165 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV68518821; called by muse, varscan2
- C6 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 242/746 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54715678; called by muse, mutect2, varscan2
- CA12 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51607407; called by muse, mutect2, varscan2
- CABP5 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV53153676; called by muse, mutect2
- CAND1 | c.3218A>T p.H1073L | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV73389738; called by muse, mutect2, varscan2
- CBFB | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52000409; called by muse, varscan2
- CBLN2 | c.437G>C p.S146T | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.489); catalogued as COSV54052558; called by muse, mutect2, varscan2
- CCDC6 | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 105/264 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54059171; called by muse, mutect2, varscan2
- CCDC96 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 133/160 reads (83%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV59509207; called by muse, mutect2, varscan2
- CCN6 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 6/69 reads (9%) | catalogued as rs1554314520, COSV100037061; called by muse, mutect2
- CCNE2 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 70/129 reads (54%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV57377131; called by muse, mutect2, varscan2
- CD109 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54654865; called by muse, mutect2
- CD1B | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 188/412 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63804594, COSV63804943; called by muse, mutect2, varscan2
- CD99L2 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57988401; called by muse, mutect2, varscan2
- CDH18 | c.665A>T p.H222L | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV104386327, COSV56949716; called by muse, mutect2, varscan2
- CDH9 | c.347T>A p.L116Q | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50384163; called by muse, mutect2, varscan2
- CDR1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868811042, COSV65164314; called by muse, mutect2, varscan2
- CENPE | c.439C>G p.Q147E | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs889930003, COSV54387273; called by muse, mutect2, varscan2
- CFAP44 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 25/628 reads (4%) | catalogued as COSV55614704; called by muse, mutect2
- CFHR2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as rs370528458, COSV66381914; called by muse, mutect2, varscan2
- CGB7 | c.384G>C p.L128F | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.06); catalogued as rs776569449, COSV100655035, COSV62281759; called by muse, mutect2, varscan2
- CLVS2 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 113/128 reads (88%) | catalogued as rs767545171, COSV51567651; called by muse, mutect2, varscan2
- CNKSR2 | c.1656A>C p.K552N | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV54263500; called by muse, mutect2, varscan2
- COBLL1 | c.2677G>A p.D893N (on ENST00000392717; = p.D855N on NM_014900.5) | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52073695; called by muse, mutect2, varscan2
- COL13A1 | c.765A>C p.K255N (on ENST00000398978 / NM_001130103.2; = p.K198N on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.651); catalogued as COSV62573429; called by muse, mutect2, varscan2
- COL15A1 | c.3922G>C p.D1308H | Missense Mutation (SNP) | VAF 84/164 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66648126; called by muse, mutect2, varscan2
- COL3A1 | c.1762-1G>T p.X588_splice | Splice Site (SNP) | VAF 68/150 reads (45%) | catalogued as COSV58591126, COSV58594445; called by muse, mutect2, varscan2
- COMMD8 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as COSV67500677; called by muse, mutect2, varscan2
- CORO7 | c.946C>G p.P316A | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52032972; called by muse, mutect2, varscan2
- CPT1A | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 49/51 reads (96%) | SIFT tolerated (0.32); PolyPhen benign (0.091); catalogued as COSV55759628; called by muse, mutect2, varscan2
- CREBBP | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 51/159 reads (32%) | catalogued as COSV52135898; called by muse, mutect2, varscan2
- CSMD2 | c.4036G>T p.A1346S | Missense Mutation (SNP) | VAF 186/613 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.039); catalogued as COSV53946584; called by muse, mutect2, varscan2
- CSNK1A1L | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65790031; called by muse, mutect2, varscan2
- CTDSP1 | c.472-2A>T p.X158_splice | Splice Site (SNP) | VAF 15/45 reads (33%) | catalogued as COSV56090487; called by muse, mutect2, varscan2
- CTSK | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 172/533 reads (32%) | catalogued as COSV55013389; called by muse, mutect2, varscan2
- CTTNBP2 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50448602; called by muse, mutect2, varscan2
- CUX1 | c.1108G>A p.E370K (on ENST00000292535 / NM_181552.4; = p.E381K on NM_001913.5) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.16); catalogued as rs782320090, COSV52910563; called by mutect2, varscan2
- DECR2 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV54795895; called by muse, mutect2, varscan2
- DEFB110 | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV64484788; called by muse, mutect2, varscan2
- DGKK | c.2100A>G p.I700M | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV65709070; called by muse, mutect2, varscan2
- DMXL2 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756757123, COSV51853176; called by muse, mutect2, varscan2
- DNAH1 | c.12382C>A p.L4128M | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as COSV56234859; called by muse, mutect2
- DNAH11 | c.4360G>C p.E1454Q | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs985818251, COSV60973258; called by muse, mutect2, varscan2
- DNAH5 | c.9161C>G p.S3054* | Nonsense Mutation (SNP) | VAF 75/289 reads (26%) | catalogued as COSV54244447; called by muse, mutect2, varscan2
- DNAH7 | c.7454G>A p.R2485H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs766897304, COSV56773922; called by muse, mutect2
- DNAJB5 | c.490C>A p.R164S | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV56626561, COSV56627032; called by muse, mutect2, varscan2
- DOCK3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 63/78 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV56541431; called by muse, mutect2, varscan2
- DPP9 | c.490G>T p.D164Y (on ENST00000598800; = p.D193Y on NM_139159.5) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53590008, COSV53593505; called by muse, mutect2, varscan2
- DSG4 | c.2557G>T p.E853* | Nonsense Mutation (SNP) | VAF 120/227 reads (53%) | catalogued as COSV57396040; called by muse, mutect2, varscan2
- DUSP16 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV53809284; called by muse, mutect2, varscan2
- EFCAB6 | c.4039G>T p.D1347Y | Missense Mutation (SNP) | VAF 286/645 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV53069566; called by muse, mutect2, varscan2
- ELOF1 | c.188-1G>C p.X63_splice | Splice Site (SNP) | VAF 65/250 reads (26%) | catalogued as COSV99370640; called by muse, mutect2, varscan2
- EPHB6 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs756409968, COSV67420296; called by muse, mutect2, varscan2
- EPPK1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs369129283; called by muse, mutect2, varscan2
- ERBB2 | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 121/351 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs1393814915, COSV54078707; called by muse, mutect2, varscan2
- EYA4 | c.581-1G>C p.X194_splice | Splice Site (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100765069, COSV62058516; called by muse, mutect2, varscan2
- F5 | c.4168G>C p.E1390Q | Missense Mutation (SNP) | VAF 151/377 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV63125502; called by muse, mutect2, varscan2
- FAM135B | c.4156G>C p.V1386L | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs764651487, COSV52730852, COSV52745568; called by muse, mutect2, varscan2
- FAM135B | c.3253G>A p.D1085N | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV52745589, COSV52748374; called by muse, mutect2, varscan2
- FAM135B | c.1462A>T p.T488S | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.162); catalogued as COSV52745603; called by muse, mutect2, varscan2
- FAM161A | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV56768106; called by muse, mutect2
- FCRL4 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.132); catalogued as COSV54864946; called by muse, mutect2
- FGD1 | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV64309379; called by muse, mutect2, varscan2
- FHL3 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV65952781; called by muse, mutect2
- FLG2 | c.5926C>G p.H1976D | Missense Mutation (SNP) | VAF 281/926 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV66170706, COSV66171646; called by muse, mutect2, varscan2
- FLG2 | c.4085G>A p.R1362K | Missense Mutation (SNP) | VAF 194/424 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV66171653; called by muse, mutect2, varscan2
- FLT3 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 133/621 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as COSV54048059; called by muse, mutect2, varscan2
- FMR1NB | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 79/119 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV65072800; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 24/170 reads (14%) | catalogued as rs752538869; called by mutect2, varscan2
- FSCB | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 167/190 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV61219215; called by muse, mutect2, varscan2
- GABRA4 | c.1289C>A p.A430D | Missense Mutation (SNP) | VAF 101/111 reads (91%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.617); catalogued as COSV51933128; called by muse, mutect2, varscan2
- GFOD1 | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV64953351; called by muse, mutect2, varscan2
- GJC1 | c.627C>G p.C209W | Missense Mutation (SNP) | VAF 84/105 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57912407; called by muse, mutect2, varscan2
- GJC1 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 85/105 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57912418; called by muse, mutect2, varscan2
- GLT8D1 | c.238dup p.A80Gfs*37 | Frame Shift Ins (INS) | VAF 11/70 reads (16%) | catalogued as rs754869681; called by mutect2, varscan2
- GLUD2 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV60152768; called by muse, mutect2
- GOLIM4 | c.1176G>A p.E392= | Splice Region (SNP) | VAF 73/1520 reads (5%) | catalogued as rs1204579949, COSV58331332; called by muse, mutect2
- GON4L | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 164/285 reads (58%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1343729486, COSV55200597; called by muse, mutect2, varscan2
- GP5 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 245/324 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV55468311; called by muse, mutect2, varscan2
- GPR137 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV57403440, COSV57404040; called by muse, mutect2, varscan2
- GPR37 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV58258968; called by muse, mutect2, varscan2
- GPRASP1 | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 212/1040 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100851048, COSV64356245; called by muse, mutect2, varscan2
- GRIN2B | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 63/116 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.017); catalogued as rs749839263, COSV74207229; called by muse, mutect2, varscan2
- GRM8 | c.1994C>A p.A665D | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58856325; called by muse, mutect2, varscan2
- H2BC7 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100587227, COSV61911476, COSV61912249; called by muse, mutect2, varscan2
- HEATR3 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as COSV53531034; called by muse, mutect2, varscan2
- HELB | c.386T>C p.L129P | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56075425; called by muse, mutect2, varscan2
- HELB | c.1195G>T p.D399Y | Missense Mutation (SNP) | VAF 148/235 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV56073807, COSV56075434; called by muse, mutect2, varscan2
- HLCS | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV60796857; called by muse, mutect2, varscan2
- HNRNPD | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 30/37 reads (81%) | catalogued as COSV58314597, COSV58314717; called by muse, mutect2, varscan2
- IDH3G | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54209404; called by muse, mutect2, varscan2
- IGKV1-5 | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs182340840; called by muse, mutect2, varscan2
- IGKV6D-21 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 142/250 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs753016861; called by muse, mutect2, varscan2
- IGSF11 | c.846T>G p.N282K (on ENST00000393775 / NM_001015887.3; = p.N281K on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/400 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61176158; called by muse, mutect2, varscan2
- IGSF9B | c.439dup p.Q147Pfs*10 | Frame Shift Ins (INS) | VAF 14/104 reads (13%) | catalogued as rs748943611; called by mutect2, varscan2
- IL12B | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.16); catalogued as COSV51455515; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1372+1G>T p.X458_splice | Splice Site (SNP) | VAF 49/147 reads (33%) | catalogued as COSV100151935, COSV56288478; called by muse, mutect2, varscan2
- IL1RAPL2 | c.980C>A p.A327E | Missense Mutation (SNP) | VAF 103/185 reads (56%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.587); catalogued as COSV61161110, COSV61173588; called by muse, mutect2, varscan2
- ISG20L2 | c.865dup p.L289Pfs*6 | Frame Shift Ins (INS) | VAF 33/226 reads (15%) | catalogued as rs761558950; called by mutect2, varscan2
- ITIH2 | c.743A>T p.H248L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64434657; called by muse, mutect2, varscan2
- JAKMIP2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as rs142259346; called by muse, mutect2
- KALRN | c.2821G>A p.E941K | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53775772; called by muse, mutect2
- KCNF1 | c.1219A>T p.N407Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV54464936; called by muse, mutect2, varscan2
- KDM4A | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100969371, COSV64960339; called by muse, mutect2, varscan2
- KIAA1210 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.415); catalogued as COSV68175254; called by muse, mutect2
- KIF22 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV50717391; called by muse, mutect2, varscan2
- KLHL38 | c.1565A>C p.K522T | Missense Mutation (SNP) | VAF 206/431 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV58088623; called by muse, mutect2, varscan2
- KMT2C | c.5371C>T p.Q1791* | Nonsense Mutation (SNP) | VAF 350/511 reads (68%) | catalogued as COSV51427498; called by muse, mutect2, varscan2
- KPNA6 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV65361675; called by muse, mutect2
- KRIT1 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV60667337; called by muse, mutect2
- LCK | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60740534; called by muse, mutect2, varscan2
- LELP1 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 163/433 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64202674; called by muse, mutect2, varscan2
- LEO1 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 151/181 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs751561202, COSV55175183, COSV55176232; called by muse, mutect2, varscan2
- LONRF3 | c.794A>T p.K265M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV59155803; called by muse, mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 30/179 reads (17%) | catalogued as rs746133895; called by mutect2, varscan2
- LPA | c.5015C>A p.T1672K | Missense Mutation (SNP) | VAF 200/223 reads (90%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV60307959; called by muse, mutect2, varscan2
- MACIR | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 42/48 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100174653, COSV60634564; called by muse, mutect2, varscan2
- MAGEA11 | c.182C>G p.P61R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.588); catalogued as COSV60757720; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 26/118 reads (22%) | catalogued as rs777328830; called by mutect2, varscan2
- MATN4 | c.1340C>A p.A447D (on ENST00000372754; = p.A406D on NM_003833.4) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | PolyPhen benign (0.02); catalogued as COSV61352414; called by muse, mutect2, varscan2
- MBTPS2 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 13/251 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as COSV63412216; called by muse, mutect2
- MBTPS2 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV65269809; called by muse, mutect2, varscan2
- MCF2 | c.2383G>C p.D795H | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV58492236; called by muse, mutect2, varscan2
- MCTP1 | c.1291C>G p.L431V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV56528538; called by muse, mutect2, varscan2
- MDN1 | c.14800G>A p.E4934K | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV65524226; called by muse, mutect2
- MICU1 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV63146994; called by muse, mutect2, varscan2
- MIER3 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61229961; called by muse, mutect2, varscan2
- MOG | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867181204, COSV65321620; called by muse, mutect2, varscan2
- MRPL30 | c.348G>C p.L116F | Missense Mutation (SNP) | VAF 10/298 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57667513; called by muse, mutect2
- MSN | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 163/255 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64305127; called by muse, mutect2, varscan2
- MTMR14 | c.1614-1G>A p.X538_splice | Splice Site (SNP) | VAF 9/118 reads (8%) | catalogued as COSV56006836, COSV99931340; called by muse, mutect2
- MUC16 | c.37335C>T p.L12445= | Splice Region (SNP) | VAF 41/1360 reads (3%) | catalogued as COSV67484023; called by muse, mutect2
- MUC16 | c.37333C>T p.L12445F | Missense Mutation (SNP) | VAF 43/1416 reads (3%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.998); catalogued as COSV67484026; called by muse, mutect2
- MUC16 | c.20792C>T p.S6931L | Missense Mutation (SNP) | VAF 257/1036 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.281); catalogued as COSV67468635, COSV67478991; called by muse, mutect2, varscan2
- MUC17 | c.11787C>G p.I3929M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.854); catalogued as COSV60288339, COSV60299116; called by muse, mutect2, varscan2
- MYH2 | c.3453G>T p.E1151D | Missense Mutation (SNP) | VAF 38/51 reads (75%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.927); catalogued as COSV55445437; called by muse, varscan2
- MYO1H | c.1504C>A p.R502S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV60449419; called by muse, mutect2, varscan2
- MYO5B | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 238/403 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53211787; called by muse, mutect2, varscan2
- MYO6 | c.1775A>T p.Q592L | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV64120661; called by muse, mutect2, varscan2
- MYT1L | c.2871C>A p.C957* | Nonsense Mutation (SNP) | VAF 46/89 reads (52%) | catalogued as COSV67704147; called by muse, mutect2, varscan2
- NAALADL2 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372321787, COSV69159199; called by muse, mutect2
- NAV2 | c.2980G>A p.D994N (on ENST00000396087 / NM_001244963.2; = p.D971N on NM_145117.5) | Missense Mutation (SNP) | VAF 160/192 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60663487; called by muse, mutect2, varscan2
- NAV3 | c.1852C>G p.Q618E | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57103325; called by muse, mutect2, varscan2
- NIF3L1 | c.139G>A p.E47K (on ENST00000409020 / NM_001369444.1; = p.E20K on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs752042784, COSV53770007; called by muse, mutect2, varscan2
- NLGN2 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 73/81 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV57211518; called by muse, mutect2, varscan2
- NOM1 | c.1168G>A p.A390T | Missense Mutation (SNP) | VAF 149/206 reads (72%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as rs757961293, COSV51980301; called by muse, mutect2, varscan2
- NOX3 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs1416844681, COSV50159861; called by muse, mutect2, varscan2
- NPC1L1 | c.2945C>T p.S982L | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs757331689, COSV56928916; called by muse, mutect2, varscan2
- NR0B1 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV66764548; called by muse, mutect2, varscan2
- NR1H3 | c.601dup p.Q201Pfs*25 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | catalogued as rs779801455; called by mutect2, varscan2
- NTRK3 | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1305137414, COSV58136865; called by muse, mutect2, varscan2
- OR10R2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 19/603 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs1212879955, COSV63769320; called by muse, mutect2
- OR13C5 | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 16/322 reads (5%) | catalogued as COSV66165185; called by muse, mutect2
- OR2G6 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV58575506; called by muse, mutect2, varscan2
- OR2T8 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60664219; called by muse, mutect2, varscan2
- OR4A15 | c.909A>T p.K303N | Missense Mutation (SNP) | VAF 78/92 reads (85%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); catalogued as rs1565113250, COSV104406989, COSV59036908; called by muse, mutect2, varscan2
- OR51I1 | c.130A>T p.N44Y | Missense Mutation (SNP) | VAF 202/241 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66508837, COSV99061841; called by muse, mutect2, varscan2
- OR52N4 | c.503T>A p.L168Q | Missense Mutation (SNP) | VAF 164/196 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57892198; called by muse, mutect2, varscan2
- OR5B12 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as rs751830533; called by muse, mutect2, varscan2
- OR5F1 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 55/59 reads (93%) | catalogued as rs1302231079, COSV53548049; called by muse, mutect2, varscan2
- OR5H1 | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 5/151 reads (3%) | catalogued as COSV63403200; called by muse, mutect2
- OR8B12 | c.442T>C p.Y148H | Missense Mutation (SNP) | VAF 134/141 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV104405629, COSV60912534; called by muse, mutect2, varscan2
- OR8S1 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV59600574; called by muse, mutect2, varscan2
- OTOGL | c.3403G>C p.E1135Q (on ENST00000547103; = p.E1126Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV101509181; called by muse, mutect2, varscan2
- OXLD1 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs370129678, COSV61303749; called by muse, mutect2, varscan2
- PALB2 | c.2338G>A p.G780S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55168956; called by muse, mutect2, varscan2
- PARD6G | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV62062297; called by muse, mutect2
- PARP16 | c.664G>C p.D222H | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs756333312, COSV56035523, COSV56036277; called by muse, mutect2, varscan2
- PCDH17 | c.3208C>T p.Q1070* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as COSV64975006; called by muse, mutect2, varscan2
- PCDHB4 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs782252909, COSV52025608; called by muse, mutect2, varscan2
- PCDHGC5 | c.1610G>C p.R537P | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52762923; called by muse, mutect2, varscan2
- PDE3A | c.1729C>G p.Q577E | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62979967; called by muse, mutect2, varscan2
- PEG3 | c.3399C>A p.C1133* | Nonsense Mutation (SNP) | VAF 351/757 reads (46%) | catalogued as COSV55643380; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 36/311 reads (12%) | catalogued as rs749506841; called by mutect2, varscan2
- PKHD1L1 | c.3809C>G p.T1270R | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as COSV65744747; called by muse, mutect2, varscan2
- PLXNB3 | c.5426A>C p.K1809T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62796384, COSV62800796; called by muse, mutect2, varscan2
- POLR2B | c.1525G>T p.V509L | Missense Mutation (SNP) | VAF 83/105 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV58902148; called by muse, mutect2, varscan2
- PSMD3 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 231/268 reads (86%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as COSV52859135; called by muse, mutect2, varscan2
- PTBP2 | c.469G>T p.V157F (on ENST00000426398 / NM_001300986.2; = p.V149F on NM_021190.4) | Missense Mutation (SNP) | VAF 86/98 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV64626035; called by muse, mutect2, varscan2
- PTK2 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 71/487 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as COSV61790335; called by muse, mutect2, varscan2
- PTPRC | c.2924C>T p.S975F | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61418724; called by muse, mutect2, varscan2
- PTPRN2 | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867851806, COSV67055583; called by muse, mutect2
- PWWP3B | c.1355A>C p.Q452P | Missense Mutation (SNP) | VAF 38/224 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.892); catalogued as COSV61801172; called by muse, mutect2, varscan2
- RAB39B | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65625067; called by muse, varscan2
- RABGEF1 | c.362C>T p.S121F (on ENST00000439720 / NM_001287061.2; = p.S108F on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53161746, COSV53164441; called by muse, mutect2, varscan2
- RASAL1 | c.1092C>A p.H364Q | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55658788; called by muse, mutect2, varscan2
- RBMX | c.899C>A p.P300H | Missense Mutation (SNP) | VAF 240/575 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV104413319, COSV57810843; called by muse, mutect2, varscan2
- RBMX | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.03); catalogued as COSV100284690, COSV57810847; called by muse, mutect2, varscan2
- RGS3 | c.2832G>T p.E944D (on ENST00000350696 / NM_001282923.2; = p.E663D on NM_130795.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV59520524; called by muse, mutect2, varscan2
- RHAG | c.641-2A>G p.X214_splice | Splice Site (SNP) | VAF 110/118 reads (93%) | catalogued as COSV57705735; called by muse, mutect2, varscan2
- RIMS1 | c.3643T>C p.S1215P | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as COSV53475370; called by muse, mutect2, varscan2
- RNASEL | c.2072A>G p.Y691C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62377654; called by muse, mutect2, varscan2
- RNF113A | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV65097714; called by muse, mutect2
- RNF144A | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV57984577; called by muse, mutect2
- SCYL2 | c.2453A>G p.N818S | Missense Mutation (SNP) | VAF 139/225 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565980963, COSV62570245; called by muse, mutect2, varscan2
- SDF2 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55932206; called by muse, mutect2
- SERBP1 | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.39); PolyPhen benign (0.182); catalogued as COSV63414120; called by muse, mutect2, varscan2
- SETD2 | c.7108G>T p.V2370F | Missense Mutation (SNP) | VAF 98/116 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57446958; called by muse, mutect2, varscan2
- SETDB1 | c.2462A>G p.D821G | Missense Mutation (SNP) | VAF 112/382 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54985953; called by muse, mutect2, varscan2
- SF3A1 | c.1531del p.R511Gfs*103 | Frame Shift Del (DEL) | VAF 80/176 reads (45%) | catalogued as COSV53168668; called by mutect2, varscan2
- SGO2 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63416991, COSV63418758; called by muse, mutect2
- SGO2 | c.3204G>C p.Q1068H | Missense Mutation (SNP) | VAF 107/140 reads (76%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as COSV63417000; called by muse, mutect2, varscan2
- SH3KBP1 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 24/345 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65643856; called by muse, mutect2
- SH3KBP1 | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 229/308 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV65643863; called by muse, mutect2, varscan2
- SH3PXD2A | c.1646G>A p.R549Q (on ENST00000369774 / NM_001365079.1; = p.R521Q on NM_014631.2) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs777092853, COSV60118302; called by muse, mutect2, varscan2
- SI | c.4804G>T p.A1602S | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.158); catalogued as COSV52294142; called by muse, mutect2, varscan2
- SIDT2 | c.1872G>C p.V624= | Splice Region (SNP) | VAF 57/68 reads (84%) | catalogued as COSV54059682; called by muse, mutect2, varscan2
- SIPA1L3 | c.3710G>A p.G1237E | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs764236428, COSV55921646; called by muse, mutect2, varscan2
- SLC12A6 | c.3005G>A p.R1002Q (on ENST00000354181 / NM_001365088.1; = p.R951Q on NM_005135.2) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs778685963, COSV51629531; called by muse, mutect2, varscan2
- SLC25A3 | c.595A>T p.T199S (on ENST00000228318 / NM_005888.3; = p.T198S on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.254); catalogued as rs754743636, COSV51847160; called by muse, mutect2, varscan2
- SLC25A3 | c.830G>C p.C277S (on ENST00000228318 / NM_005888.3; = p.C276S on NM_002635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51847174; called by muse, mutect2, varscan2
- SLC25A38 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56195152; called by muse, mutect2
- SLC25A5 | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 291/483 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as rs755053633, COSV58625536, COSV58629168; called by muse, mutect2, varscan2
- SLC38A8 | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV55308865; called by muse, mutect2, varscan2
- SLC44A2 | c.692C>G p.S231C | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV59834749; called by muse, mutect2
- SLC66A3 | c.267C>A p.N89K | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV54468041; called by muse, mutect2, varscan2
- SMAD3 | c.1023G>C p.K341N | Missense Mutation (SNP) | VAF 31/355 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59288132; called by muse, mutect2
- SNAP91 | c.783A>T p.K261N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52130635; called by muse, mutect2, varscan2
- SNX7 | c.217A>G p.M73V | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT tolerated (0.92); PolyPhen benign (0.012); catalogued as COSV60271018; called by muse, mutect2, varscan2
- SPECC1L | c.3008C>T p.S1003L | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV58660289, COSV58660732; called by muse, mutect2, varscan2
- SPTLC3 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 60/1879 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as rs941422250, COSV65465492; called by muse, mutect2
- SRGAP3 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV64533082, COSV64537669; called by muse, mutect2
- SRSF10 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT tolerated (0.82); PolyPhen benign (0.184); catalogued as rs772353036; called by muse, mutect2, varscan2
- SSH2 | c.1872dup p.M625Hfs*4 | Frame Shift Ins (INS) | VAF 12/94 reads (13%) | catalogued as rs35554312; called by mutect2, varscan2
- ST6GALNAC1 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 181/198 reads (91%) | PolyPhen benign (0); catalogued as COSV50078434; called by muse, mutect2, varscan2
- STN1 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 112/182 reads (62%) | catalogued as COSV56545705; called by muse, varscan2
- SUGP1 | c.887+2T>A p.X296_splice | Splice Site (SNP) | VAF 62/260 reads (24%) | catalogued as COSV55923372; called by muse, mutect2
- SULT1C3 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 87/126 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61254314; called by muse, mutect2, varscan2
- TBCK | c.478G>T p.E160* (on ENST00000273980 / NM_001163436.4; = p.E97* on NM_033115.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV56760790; called by muse, mutect2, varscan2
- TEX15 | c.1895G>T p.S632I (on ENST00000256246; = p.S1015I on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs1413458735, COSV56351716; called by muse, mutect2, varscan2
- THBS2 | c.1990G>T p.E664* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as rs1314889912, COSV64681371, COSV64682224; called by muse, mutect2, varscan2
- TLCD3B | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV54227883; called by muse, mutect2, varscan2
- TMC4 | c.2134C>G p.L712V (on ENST00000617472 / NM_001145303.3; = p.L706V on NM_144686.4) | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.046); catalogued as rs782573312, COSV55366855; called by muse, mutect2, varscan2
- TMPRSS11F | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as rs377605520; called by muse, mutect2, varscan2
- TMPRSS15 | c.2528T>A p.L843Q | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53046065; called by muse, mutect2, varscan2
- TNIK | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 135/453 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as COSV52691640; called by muse, mutect2, varscan2
- TOMM22 | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV53266058; called by muse, mutect2, varscan2
- TOR1AIP2 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.105); catalogued as COSV62626897; called by muse, mutect2, varscan2
- TOX3 | c.1117C>G p.Q373E | Missense Mutation (SNP) | VAF 185/906 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as rs745322355, COSV54871551; called by muse, mutect2, varscan2
- TRBV27 | c.136A>G p.M46V | Missense Mutation (SNP) | VAF 110/471 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.91); catalogued as rs746170629; called by muse, mutect2, varscan2
- TRIM39 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV64956262; called by muse, mutect2, varscan2
- TRIML1 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 58/75 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV60196218; called by muse, mutect2, varscan2
- TTN | c.97517G>T p.G32506V (on ENST00000591111; = p.G25082V on NM_003319.4) | Missense Mutation (SNP) | VAF 86/285 reads (30%) | PolyPhen benign (0.001); catalogued as COSV60258109; called by muse, mutect2, varscan2
- TTN | c.85823C>T p.P28608L (on ENST00000591111; = p.P21184L on NM_003319.4) | Missense Mutation (SNP) | VAF 253/385 reads (66%) | PolyPhen probably damaging (0.999); catalogued as COSV60258238; called by muse, mutect2, varscan2
- UPF3B | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV52231117; called by muse, mutect2, varscan2
- USH2A | c.11661G>T p.W3887C | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56415524; called by muse, mutect2, varscan2
- USP29 | c.57G>C p.M19I | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV54242086; called by muse, mutect2, varscan2
- USP34 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV68404702; called by muse, mutect2, varscan2
- USP6 | c.3734G>A p.R1245Q | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.06); catalogued as rs761581553, COSV51472892, COSV51492460; called by muse, varscan2
- VAC14 | c.152A>T p.H51L | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV55756648; called by muse, mutect2, varscan2
- VSIG4 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 8/208 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66074575; called by muse, mutect2
- VWA8 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55702451; called by muse, mutect2, varscan2
- WDR17 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV54580670; called by muse, mutect2
- WIPF1 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV55818947; called by muse, mutect2, varscan2
- XAB2 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs747797751, COSV50333790; called by muse, mutect2, varscan2
- XIRP2 | c.7987G>T p.E2663* (on ENST00000628543; = p.E2838* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 19/205 reads (9%) | catalogued as COSV54687438, COSV99746734; called by muse, mutect2
- ZAP70 | c.1139C>A p.T380K | Missense Mutation (SNP) | VAF 139/373 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53856361; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1275G>C p.Q425H | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as COSV57639735; called by muse, mutect2
- ZMYM6 | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.727); catalogued as rs774508184, COSV64121039; called by muse, mutect2, varscan2
- ZNF106 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV55520454; called by muse, mutect2, varscan2
- ZNF184 | c.1523G>T p.G508V | Missense Mutation (SNP) | VAF 69/85 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53005216; called by muse, mutect2, varscan2
- ZNF184 | c.1522G>A p.G508R | Missense Mutation (SNP) | VAF 68/83 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV53005226; called by muse, mutect2, varscan2
- ZNF236 | c.2557G>T p.A853S | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV53494723; called by muse, mutect2, varscan2
- ZNF275 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.44); catalogued as COSV64705183; called by muse, mutect2, varscan2
- ZNF420 | c.1314G>C p.Q438H | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV58495617; called by muse, mutect2, varscan2
- ZNF420 | c.1902G>C p.Q634H | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV58495622; called by muse, mutect2, varscan2
- ZNF423 | c.2307G>T p.K769N (on ENST00000563137 / NM_001379286.1; = p.K761N on NM_015069.4) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV52200344; called by muse, mutect2, varscan2
- ZNF43 | c.2201A>C p.Y734S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61685310; called by muse, mutect2, varscan2
- ZNF536 | c.2122G>T p.G708W | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62827399, COSV62831324; called by muse, mutect2, varscan2
- ZNF547 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 124/3136 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56581608; called by muse, mutect2
- ZNF614 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 140/618 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as rs1192118002, COSV54545137; called by muse, mutect2, varscan2
- ZNF622 | c.1013A>T p.D338V | Missense Mutation (SNP) | VAF 106/594 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs751439032, COSV58074947; called by muse, mutect2, varscan2
- ZNF823 | c.728C>T p.T243M (on ENST00000341191 / NM_001297610.2; = p.T199M on NM_017507.2) | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375817352; called by muse, mutect2
- ZNF831 | c.3442C>G p.P1148A | Missense Mutation (SNP) | VAF 27/28 reads (96%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV64043788; called by muse, mutect2, varscan2
- ZPLD1 | c.774C>A p.D258E (on ENST00000466937 / NM_001329788.1; = p.D274E on NM_175056.2) | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); catalogued as COSV60355459, COSV60356161; called by muse, mutect2, varscan2
- BTBD7 | c.299C>A p.A100E | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C1orf116 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2
- CDC45 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2
- FLG | c.6844C>T p.P2282S | Missense Mutation (SNP) | VAF 68/396 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGKV1D-42 | c.230A>C p.H77P | Missense Mutation (SNP) | VAF 70/94 reads (74%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH7 | c.3235G>C p.E1079Q | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.273); called by muse, mutect2
- KMT2D | c.10108dup p.Q3370Pfs*53 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- PCDHGA8 | c.1694_1695delinsT p.P565Lfs*24 | Frame Shift Del (DEL) | VAF 37/91 reads (41%) | called by pindel, varscan2*
- PCIF1 | c.2053del p.E685Rfs*33 | Frame Shift Del (DEL) | VAF 25/36 reads (69%) | called by mutect2, pindel, varscan2
- PDCD11 | c.3413G>A p.S1138N | Missense Mutation (SNP) | VAF 53/480 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); called by muse, mutect2
- PPP2R2A | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- RAD54L2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- REG3A | c.205del p.Q69Rfs*24 | Frame Shift Del (DEL) | VAF 82/128 reads (64%) | called by mutect2, varscan2
- SPATA31A1 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 148/477 reads (31%) | called by muse, mutect2, varscan2
- TP53BP2 | c.873_874insG p.Q292Afs*8 (on ENST00000343537 / NM_001031685.3; = p.Q163Afs*8 on NM_005426.2) | Frame Shift Ins (INS) | VAF 32/104 reads (31%) | called by mutect2, varscan2
- TRBV24-1 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 101/444 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TTN | c.44678del p.G14893Efs*11 (on ENST00000591111; = p.G7469Efs*11 on NM_003319.4) | Frame Shift Del (DEL) | VAF 25/60 reads (42%) | called by mutect2, pindel, varscan2
- ACOX2 | c.1131C>T p.N377= | Silent (SNP) | VAF 90/107 reads (84%) | catalogued as COSV57150290; called by muse, mutect2, varscan2
- AGT | c.1347T>A p.P449= | Silent (SNP) | VAF 284/726 reads (39%) | catalogued as COSV64185259; called by muse, mutect2, varscan2
- AHCTF1 | c.633A>G p.S211= (on ENST00000366508; = p.S185= on NM_015446.5) | Silent (SNP) | VAF 62/126 reads (49%) | catalogued as rs780758041, COSV58253598; called by muse, mutect2, varscan2
- ARF1 | c.189C>T p.F63= | Silent (SNP) | VAF 13/236 reads (6%) | catalogued as COSV99683156; called by muse, mutect2
- ARHGAP5 | c.4508G>A p.*1503= (on ENST00000345122 / NM_001030055.2; = p.*1502= on NM_001173.3) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV53735523; called by muse, mutect2, varscan2
- ARHGEF26 | c.1629A>G p.L543= | Silent (SNP) | VAF 89/190 reads (47%) | catalogued as rs1415204513, COSV62850289; called by muse, mutect2, varscan2
- ASXL1 | c.858C>T p.F286= | Silent (SNP) | VAF 77/402 reads (19%) | catalogued as COSV60117269; called by muse, mutect2, varscan2
- ASXL1 | c.2071C>T p.L691= | Silent (SNP) | VAF 14/174 reads (8%) | catalogued as COSV60117286; called by muse, mutect2
- BMS1 | c.3072G>A p.V1024= | Silent (SNP) | VAF 16/141 reads (11%) | catalogued as COSV65735015; called by muse, mutect2, varscan2
- C1orf131 | c.333C>T p.I111= | Silent (SNP) | VAF 47/106 reads (44%) | catalogued as COSV59642942; called by muse, mutect2, varscan2
- CADM1 | c.531C>T p.I177= | Silent (SNP) | VAF 68/182 reads (37%) | catalogued as COSV59002367, COSV59019384; called by muse, mutect2, varscan2
- CEMIP2 | c.2112C>G p.L704= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as COSV65488773; called by muse, mutect2, varscan2
- CHIA | c.249G>A p.L83= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV100588666, COSV58477377; called by muse, mutect2
- CNTN2 | c.1263G>T p.L421= | Silent (SNP) | VAF 125/329 reads (38%) | catalogued as COSV59352086; called by muse, mutect2, varscan2
- CREBBP | c.1810C>T p.L604= | Silent (SNP) | VAF 7/148 reads (5%) | catalogued as COSV52135887; called by muse, mutect2
- DDR2 | c.1986C>T p.L662= | Silent (SNP) | VAF 79/379 reads (21%) | catalogued as COSV63369336, COSV63373392; called by muse, mutect2, varscan2
- DNAH11 | c.3198T>A p.A1066= | Silent (SNP) | VAF 20/461 reads (4%) | called by muse, mutect2
- EFCAB5 | c.711G>A p.L237= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV57934836; called by muse, mutect2, varscan2
- ENPEP | c.2463T>C p.Y821= | Silent (SNP) | VAF 42/49 reads (86%) | catalogued as rs776616806, COSV54455723; called by muse, mutect2, varscan2
- FAM169A | c.1560G>A p.K520= | Silent (SNP) | VAF 63/69 reads (91%) | catalogued as COSV63064073; called by muse, mutect2, varscan2
- FGF12 | c.213A>G p.K71= (on ENST00000454309 / NM_021032.5; = p.K9= on NM_004113.6) | Silent (SNP) | VAF 97/383 reads (25%) | catalogued as COSV53182269; called by muse, mutect2, varscan2
- FOXD4L5 | c.828C>A p.P276= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1311805938, COSV101073114; called by mutect2, varscan2
- GALNT17 | c.1383T>C p.N461= | Silent (SNP) | VAF 54/264 reads (20%) | catalogued as COSV61182185; called by muse, mutect2, varscan2
- GCC1 | c.1932A>G p.Q644= | Silent (SNP) | VAF 117/176 reads (66%) | catalogued as COSV58463487; called by muse, mutect2, varscan2
- GIMAP6 | c.630C>T p.A210= | Silent (SNP) | VAF 401/581 reads (69%) | catalogued as COSV61034415; called by muse, mutect2, varscan2
- GPAA1 | c.438C>G p.L146= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV60156323; called by muse, mutect2, varscan2
- GPC3 | c.1065C>A p.R355= | Silent (SNP) | VAF 137/334 reads (41%) | catalogued as COSV63669765; called by muse, mutect2, varscan2
- GRIK3 | c.1077C>T p.G359= | Silent (SNP) | VAF 209/306 reads (68%) | catalogued as rs1195514120, COSV66143496; called by muse, mutect2, varscan2
- HCN1 | c.1290G>A p.K430= | Silent (SNP) | VAF 50/538 reads (9%) | catalogued as COSV57510927, COSV57529983; called by muse, mutect2
- HIP1 | c.2916G>T p.T972= | Silent (SNP) | VAF 139/216 reads (64%) | catalogued as rs375211454, COSV61190012; called by muse, mutect2, varscan2
- IGKV3D-20 | c.39C>A p.L13= | Silent (SNP) | VAF 65/209 reads (31%) | called by muse, mutect2, varscan2
- IGSF1 | c.963C>A p.P321= | Silent (SNP) | VAF 101/265 reads (38%) | catalogued as COSV63839326; called by muse, mutect2, varscan2
- IPO8 | c.1971C>T p.S657= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV56244511; called by mutect2, varscan2
- JCAD | c.1389G>C p.P463= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV64761159; called by muse, mutect2, varscan2
- KLK3 | c.315C>G p.L105= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as COSV58102153; called by muse, mutect2, varscan2
- LILRB1 | c.348G>A p.K116= (on ENST00000427581; = p.K80= on NM_006669.6) | Silent (SNP) | VAF 151/732 reads (21%) | catalogued as COSV61120894, COSV99048729; called by muse, mutect2, varscan2
- LMNA | c.216C>A p.R72= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV61543719; called by muse, mutect2, varscan2
- LYG2 | c.103C>T p.L35= | Silent (SNP) | VAF 296/601 reads (49%) | catalogued as COSV60716421; called by muse, mutect2, varscan2
- MAFF | c.33A>G p.L11= | Silent (SNP) | VAF 103/347 reads (30%) | catalogued as COSV58299562; called by muse, mutect2, varscan2
- MAP2 | c.2487C>T p.A829= | Silent (SNP) | VAF 130/243 reads (53%) | catalogued as COSV52303341; called by muse, mutect2, varscan2
- MUC16 | c.37170C>T p.F12390= | Silent (SNP) | VAF 112/2289 reads (5%) | catalogued as rs892170676; called by muse, mutect2
- MUC17 | c.9882C>G p.A3294= | Silent (SNP) | VAF 176/308 reads (57%) | catalogued as COSV60299106; called by muse, mutect2
- MUC4 | c.16215G>T p.L5405= (on ENST00000463781 / NM_018406.7; = p.L1169= on NM_004532.6) | Silent (SNP) | VAF 23/358 reads (6%) | catalogued as COSV57796718; called by muse, mutect2
- MYT1L | c.2479C>A p.R827= | Silent (SNP) | VAF 79/126 reads (63%) | catalogued as COSV67720706, COSV67728880; called by muse, mutect2, varscan2
- NEB | c.1407C>T p.G469= | Silent (SNP) | VAF 94/292 reads (32%) | catalogued as COSV51446274; called by muse, mutect2, varscan2
- NOLC1 | c.1251G>C p.L417= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV64180933; called by muse, mutect2, varscan2
- NOLC1 | c.1803G>A p.K601= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs781474264, COSV64180940, COSV64181120; called by muse, mutect2, varscan2
- NOLC1 | c.1986G>A p.L662= | Silent (SNP) | VAF 140/716 reads (20%) | catalogued as COSV64180945; called by muse, varscan2
- NOTCH3 | c.4986C>G p.V1662= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV54644556; called by muse, varscan2
- OGDH | c.2334G>T p.L778= | Silent (SNP) | VAF 91/105 reads (87%) | catalogued as COSV56055190; called by muse, mutect2, varscan2
- OR2G6 | c.874C>T p.L292= | Silent (SNP) | VAF 7/162 reads (4%) | catalogued as rs1171998356, COSV58575515; called by muse, mutect2
- OR2M5 | c.81C>T p.L27= | Silent (SNP) | VAF 16/642 reads (2%) | catalogued as COSV63546817; called by muse, mutect2
- OR52N5 | c.858G>T p.V286= | Silent (SNP) | VAF 64/91 reads (70%) | catalogued as COSV57699314; called by muse, mutect2, varscan2
- OR8B4 | c.111C>T p.F37= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV62070313; called by muse, mutect2
- PAK5 | c.2037G>A p.L679= | Silent (SNP) | VAF 92/914 reads (10%) | catalogued as COSV62034813; called by muse, mutect2, varscan2
- PAXIP1 | c.2097C>T p.F699= | Silent (SNP) | VAF 96/505 reads (19%) | catalogued as COSV68187288; called by muse, mutect2, varscan2
- PCDHGC5 | c.2253G>C p.V751= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV52762936; called by muse, mutect2
- PDSS2 | c.280C>T p.L94= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- PEX1 | c.1221C>G p.L407= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV50411057, COSV99951954; called by muse, mutect2, varscan2
- PEX5L | c.1293G>A p.V431= | Silent (SNP) | VAF 24/396 reads (6%) | catalogued as COSV55853501; called by muse, mutect2
- PIGZ | c.801C>T p.L267= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV53014334; called by muse, mutect2, varscan2
- PKD1L2 | c.2820C>G p.T940= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV55167978; called by muse, mutect2, varscan2
- PKHD1 | c.8292C>T p.L2764= | Silent (SNP) | VAF 36/155 reads (23%) | catalogued as rs756431455, COSV61890036; called by muse, mutect2, varscan2
- PLCE1 | c.4626A>G p.L1542= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV53365524; called by muse, mutect2, varscan2
- PLCH1 | c.2724A>C p.V908= (on ENST00000340059 / NM_001130960.2; = p.V900= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as COSV58207260, COSV58207311; called by muse, mutect2, varscan2
- PLEKHA6 | c.2244C>A p.I748= | Silent (SNP) | VAF 65/359 reads (18%) | catalogued as COSV55332294, COSV55338644; called by muse, mutect2, varscan2
- PLXNA1 | c.1824C>T p.S608= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as rs1213408179, COSV52531053; called by muse, mutect2
- PLXNA4 | c.3126C>T p.I1042= | Silent (SNP) | VAF 25/219 reads (11%) | catalogued as rs772829574, COSV58111958; called by muse, mutect2, varscan2
- POLR1A | c.3594G>C p.L1198= | Silent (SNP) | VAF 4/55 reads (7%) | catalogued as COSV55689628, COSV55697639; called by muse, mutect2
- PPFIA2 | c.477G>C p.R159= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV100333546, COSV61047701; called by muse, mutect2, varscan2
- PRDM13 | c.1446C>G p.L482= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV65030508; called by muse, mutect2, varscan2
- PRPF40B | c.1018C>A p.R340= (on ENST00000380281; = p.R334= on NM_012272.3) | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV56061125, COSV99979152; called by muse, mutect2, varscan2
- PSPH | c.603C>T p.I201= | Silent (SNP) | VAF 18/187 reads (10%) | catalogued as rs763944186, COSV51912750; called by muse, mutect2, varscan2
- PTPRN2 | c.2853G>A p.R951= | Silent (SNP) | VAF 9/215 reads (4%) | catalogued as rs1307364330, COSV67032777, COSV67055577; called by muse, mutect2
- PTPRO | c.3594G>A p.K1198= (on ENST00000281171 / NM_030667.3; = p.K1170= on NM_002848.4) | Silent (SNP) | VAF 13/110 reads (12%) | catalogued as COSV55506269; called by muse, mutect2, varscan2
- PXMP4 | c.330C>T p.L110= | Silent (SNP) | VAF 24/143 reads (17%) | catalogued as COSV54133980; called by muse, mutect2, varscan2
- RALGAPA1 | c.3573C>T p.I1191= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV51892851; called by muse, mutect2, varscan2
- RBM48 | c.1035A>T p.P345= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV56003417; called by mutect2, varscan2
- RGS22 | c.1962T>G p.G654= | Silent (SNP) | VAF 51/90 reads (57%) | catalogued as COSV62665928; called by muse, mutect2, varscan2
- SCN2A | c.489A>G p.T163= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs1057520898, COSV51851800; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMA6D | c.2700C>T p.I900= (on ENST00000316364 / NM_153618.2; = p.I838= on NM_020858.2) | Silent (SNP) | VAF 26/175 reads (15%) | called by muse, mutect2, varscan2
- SIGLEC14 | c.786G>T p.V262= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as COSV55782516; called by muse, mutect2, varscan2
- SLC35A4 | c.906C>G p.L302= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- SLC44A4 | c.1437C>G p.P479= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as rs1477664053, COSV57668703; called by muse, mutect2, varscan2
- SLC4A11 | c.1206C>T p.D402= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs764910925, COSV66263357; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC4A1AP | c.1614G>A p.A538= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as rs116617546, COSV58136873; called by muse, mutect2, varscan2
- STAB2 | c.4050G>A p.G1350= | Silent (SNP) | VAF 48/74 reads (65%) | catalogued as COSV66344523; called by muse, mutect2
- STAG2 | c.3414C>T p.F1138= | Silent (SNP) | VAF 10/195 reads (5%) | catalogued as COSV54368706; called by muse, mutect2
- TAP1 | c.2154C>T p.I718= | Silent (SNP) | VAF 13/214 reads (6%) | called by muse, mutect2
- TCTEX1D1 | c.420G>A p.Q140= | Silent (SNP) | VAF 110/190 reads (58%) | catalogued as COSV51076572; called by muse, varscan2
- TESK1 | c.903T>A p.R301= | Silent (SNP) | VAF 133/416 reads (32%) | catalogued as COSV52412115; called by muse, mutect2, varscan2
- THOC2 | c.195G>A p.Q65= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV55553217; called by mutect2, varscan2
- TONSL | c.1546C>A p.R516= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV68049061; called by muse, mutect2, varscan2
- TTN | c.51276C>G p.L17092= (on ENST00000591111; = p.L9668= on NM_003319.4) | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as rs766306616, COSV59989551; called by muse, mutect2, varscan2
- VANGL2 | c.1287G>C p.T429= | Silent (SNP) | VAF 140/427 reads (33%) | catalogued as rs572362079, COSV63605162; called by muse, mutect2, varscan2
- XRCC6 | c.855A>C p.P285= | Silent (SNP) | VAF 139/399 reads (35%) | catalogued as COSV63158771; called by muse, varscan2
- ZAP70 | c.555C>A p.G185= | Silent (SNP) | VAF 46/82 reads (56%) | catalogued as COSV53856351; called by muse, mutect2, varscan2
- ZEB1 | c.2106A>G p.T702= | Silent (SNP) | VAF 79/133 reads (59%) | catalogued as COSV58051594; called by muse, mutect2, varscan2
- ZNF441 | c.1620C>T p.F540= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV63540581; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701157 ins C | 3'Flank (INS) | VAF 10/78 reads (13%) | catalogued as rs760920589; called by mutect2, varscan2
- DNM1 | c.2535-1544C>T | Intron (SNP) | VAF 16/246 reads (7%) | catalogued as COSV57854990; called by muse, mutect2
- HTR2C | c.-79-11597G>A | Intron (SNP) | VAF 9/186 reads (5%) | called by muse, mutect2
- MIRLET7C | n.81G>C | RNA (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- NRP1 | c.981+4533A>G | Intron (SNP) | VAF 20/36 reads (56%) | called by mutect2, varscan2
- NTRK3 | c.1586-40598C>G | Intron (SNP) | VAF 19/409 reads (5%) | catalogued as COSV100446338; called by muse, mutect2
- SEPTIN9 | c.722-6272C>G | Intron (SNP) | VAF 45/131 reads (34%) | catalogued as rs1020983150, COSV100218094, COSV61211830; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-15171G>T | Intron (SNP) | VAF 47/134 reads (35%) | catalogued as COSV67448021; called by muse, mutect2, varscan2
- TRIM36 | c.64-7423G>A | Intron (SNP) | VAF 28/91 reads (31%) | catalogued as COSV99142343; called by muse, mutect2, varscan2
- TTN | c.34264+558dup | Intron (INS) | VAF 72/240 reads (30%) | called by mutect2, varscan2
- XIST | n.11198C>A | RNA (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
